Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-7631, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-7631-01A (Primary Tumor).

[page 1 of 15]
PATIENT: [REDACTED]

AGE/SEX: [REDACTED]

REG DR: [REDACTED]

Path #: [REDACTED]

Submit Dr: [REDACTED]

Copies to:

This is a corrected report.

Any previous versions are stored internally and are available if necessary.

SPECIMEN ID:

- A. SKIN - Upper lip margin, clip superior. Skin.,
- B. SKIN - Inferior margin clip superior, Skin.,
- C. SKIN - Inferior lateral margin, clip superior, Skin,
- D. SKIN - Lower lip margin, clip superior, skin,
- E. SKIN - mental margin clip superior, skin, F. SKIN - upper cheek margin, skin,
- G. SKIN - Nasolabial margin, skin, clip posterior,
- H. SOFT TISSUES OF HEAD AND NECK - Right lower alveolar ridge.,
- I. SOFT TISSUES OF HEAD AND NECK - Right lower gingival labial mucosa margin.,
- J. LIP, NOS - lower lip margin, clip at oral commissure.,
- K. LIP, NOS - upper lip mucosal margin,
- L. SOFT TISSUES OF HEAD AND NECK - Anterior Buccal margin clip anterior,
- M. SOFT TISSUES OF HEAD AND NECK - Posterior Buccal Margin Clip Posterior,
- N. SOFT TISSUES OF HEAD AND NECK - Retromolar trigone,
- O. SOFT TISSUES OF HEAD AND NECK - Retromandibular mucosal margin,
- P. ADIPOSE TISSUE - posterior buccal fat,
- Q. SOFT TISSUES OF HEAD AND NECK - Lower right mandible periosteal margin,
- R. SOFT TISSUE - BUCCAL RESECTION, BUCCAL MUCOSA AND CHEEK SKIN, LOWER LIP,
- S. SOFT TISSUE - RIGHT BUCCAL FAT PAD, T. NECK, NOS - LEFT NECK DISSECTION LEVEL IB,
- U. NECK, NOS - LEFT NECK DISSECTION LEVELS 2A,
- V. NECK, NOS - RIGHT NECK DISSECTION LEVEL 2B,
- W. NECK, NOS - RIGHT NECK DISSECTION LEVELS 1A, 1B, 2A, 3, 4,
- X. SOFT TISSUE - LEFT FOREARM SUBCUTANEOUS MASS,
- Y. THYROID GLAND - Right thyroid lobe with isthmus

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 2 of 15]
SPEC #: [REDACTED] (Continued)

SPECIMEN ID: (Continued)

Signed by: [REDACTED]

[REDACTED]
(Corrected Result)

Edited By: [REDACTED]

Edit Date: [REDACTED]

Edit Reason:

DIAGNOSIS EDIT/CLARIFICATION

A. UPPER LIP MARGIN, CLIP SUPERIOR, SKIN:

Skin, no malignancy seen.

B. INFERIOR MARGIN, CLIP SUPERIOR, SKIN:

Skin, no malignancy seen.

C. INFERIOR LATERAL MARGIN, CLIP SUPERIOR, SKIN:

Skin, no malignancy seen.

D. LOWER LIP MARGIN, CLIP SUPERIOR, SKIN:

Skin, no malignancy seen.

E. MENTAL MARGIN, CLIP SUPERIOR, SKIN:

Skin, no malignancy seen.

F. UPPER CHEEK MARGIN, SKIN:

Skin, no malignancy seen.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 3 of 15]
SPEC #:

(Continued)

*** FINAL DIAGNOSIS *** (Continued)

(Corrected Result)

G. NASOLABIAL MARGIN, SKIN, CLIP POSTERIOR:

Skin, no malignancy seen.

H. RIGHT LOWER ALVEOLAR RIDGE:

No malignancy seen.

I. RIGHT LOWER GINGIVAL LABIAL MUCOSA MARGIN:

No malignancy seen.

J. LOWER LIP MARGIN, CLIP AT ORAL COMMISSURE:

No malignancy seen.

K. UPPER LIP MUCOSAL MARGIN:

No malignancy seen.

L. ANTERIOR BUCCAL MARGIN, CLIP ANTERIOR:

No malignancy seen.

M. POSTERIOR BUCCAL MARGIN, CLIP POSTERIOR:

No malignancy seen.

N. RETROMOLAR TRIGONE:

No malignancy seen.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 4 of 15]
SPEC #:

(Continued)

*** FINAL DIAGNOSIS *** (Continued)

(Corrected Result)

O. RETROMANDIBULAR MUCOSAL MARGIN:

No malignancy seen.

P. POSTERIOR BUCCAL FAT:

No malignancy seen.

Q. LOWER RIGHT MANDIBLE PERIOSTEAL MARGIN:

No malignancy seen.

R. BUCCAL RESECTION, BUCCAL MUCOSA AND CHEEK SKIN, LOWER LIP:

This case was reviewed and discussed at the weekly [REDACTED] In my opinion, the buccal mucosa carcinoma is best characterized as a low to intermediate grade mucoepidermoid carcinoma.

The case was discussed with [REDACTED]

Tumor size 2.0 cm (by microscopic estimate).

No perineural or lymphovascular invasion seen.

Margins negative for tumor (see frozen section A through Q above).

S. RIGHT BUCCAL FAT PAD:

Benign adipose tissue and salivary gland tissue.

No evidence of malignancy.

T. LEFT NECK DISSECTION, LEVEL 1B:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 5 of 15]
SPEC #:

(Continued)

*** FINAL DIAGNOSIS *** (Continued)

(Corrected Result)

Lymph nodes (2); negative for tumor.

Benign salivary gland tissue; negative for tumor.

U. LEFT NECK DISSECTION LEVELS 2A:

Lymph nodes (17); negative for tumor.

V. RIGHT NECK DISSECTION LEVEL 2B:

Lymph nodes (4); negative for tumor.

W. RIGHT NECK DISSECTION LEVELS 1A, 1B, 2A, 3, 4:

Lymph nodes (25); negative for tumor.

Salivary gland tissue; no evidence of malignancy.

X. LEFT FOREARM SUBCUTANEOUS MASS:

Angiolipoma.

Y. RIGHT THYROID LOBE WITH ISTHMUS:

Multiple follicular colloid nodules consistent with goiter with focal chronic inflammation.

No evidence of malignancy.

This report is privileged, confidential and exempt from disclosure under applicable law.

If you receive this report inadvertently, please call [REDACTED] and return the report to us by mail.

[page 6 of 15]
SPEC #:

(Continued)

*** FINAL DIAGNOSIS *** (Continued)

(Corrected Result)

Signed by:

A. UPPER LIP MARGIN, CLIP SUPERIOR, SKIN:

Skin, no malignancy seen.

B. INFERIOR MARGIN, CLIP SUPERIOR, SKIN:

Skin, no malignancy seen.

C. INFERIOR LATERAL MARGIN, CLIP SUPERIOR, SKIN:

Skin, no malignancy seen.

D. LOWER LIP MARGIN, CLIP SUPERIOR, SKIN:

Skin, no malignancy seen.

E. MENTAL MARGIN, CLIP SUPERIOR, SKIN:

Skin, no malignancy seen.

F. UPPER CHEEK MARGIN, SKIN:

Skin, no malignancy seen.

G. NASOLABIAL MARGIN, SKIN, CLIP POSTERIOR:

Skin, no malignancy seen.

H. RIGHT LOWER ALVEOLAR RIDGE:

This report is privileged, confidential and exempt from disclosure under applicable law.

If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 7 of 15]
SPEC #:

(Continued)

*** FINAL DIAGNOSIS *** (Continued)

No malignancy seen.

I. RIGHT LOWER GINGIVAL LABIAL MUCOSA MARGIN:

No malignancy seen.

J. LOWER LIP MARGIN, CLIP AT ORAL COMMISSURE:

No malignancy seen.

K. UPPER LIP MUCOSAL MARGIN:

No malignancy seen.

L. ANTERIOR BUCCAL MARGIN, CLIP ANTERIOR:

No malignancy seen.

M. POSTERIOR BUCCAL MARGIN, CLIP POSTERIOR:

No malignancy seen.

N. RETROMOLAR TRIGONE:

No malignancy seen.

O. RETROMANDIBULAR MUCOSAL MARGIN:

No malignancy seen.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 8 of 15]
SPEC #:

(Continued)

*** FINAL DIAGNOSIS *** (Continued)

P. POSTERIOR BUCCAL FAT:

No malignancy seen.

Q. LOWER RIGHT MANDIBLE PERIOSTEAL MARGIN:

No malignancy seen.

R. BUCCAL RESECTION, BUCCAL MUCOSA AND CHEEK SKIN, LOWER LIP:

Invasive well differentiated squamous cell carcinoma.

Tumor size 2.0 cm (by microscopic estimate).

No perineural or lymphovascular invasion seen.

Margins negative for tumor (see frozen section A through Q above).

S. RIGHT BUCCAL FAT PAD:

Benign adipose tissue and salivary gland tissue.

No evidence of malignancy.

T. LEFT NECK DISSECTION, LEVEL 1B:

Lymph nodes (2); negative for tumor.

Benign salivary gland tissue; negative for tumor.

U. LEFT NECK DISSECTION LEVELS 2A:

Lymph nodes (17); negative for tumor.

This report is privileged, confidential and exempt from disclosure under applicable law.

If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 9 of 15]
SPEC #:

(Continued)

*** FINAL DIAGNOSIS *** (Continued)

V. RIGHT NECK DISSECTION LEVEL 2B:

Lymph nodes (4); negative for tumor.

W. RIGHT NECK DISSECTION LEVELS 1A, 1B, 2A, 3, 4:

Lymph nodes (25); negative for tumor.

Salivary gland tissue; no evidence of malignancy.

X. LEFT FOREARM SUBCUTANEOUS MASS:

Angiolipoma.

Y. RIGHT THYROID LOBE WITH ISTHMUS:

Multiple follicular colloid nodules consistent with goiter with focal chronic inflammation.

No evidence of malignancy.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 10 of 15]
SPEC #:

(Continued)

CLINICAL HISTORY-

PRE-OP DX: Not provided

PROCEDURE: Not provided

RELEVANT CLINICAL HX: Not provided

GROSS DESCRIPTION:

- A. Received fresh and labeled "Upper lip margin clip superior (skin)" is a soft tissue fragment which measures 1.4 x 0.3 x 0.1 cm. Clip margin inked in blue. Specimen submitted in toto in one cassette for frozen section.
- B. Received fresh and labeled "Inferior margin clip superior (skin)" is a soft tissue fragment measuring 0.5 x 0.3 x 0.2 cm. Clip margin inked in blue. Specimen submitted in toto in one cassette for frozen section.
- C. Received fresh and labeled "Inferior lateral margin clip superior (skin)" is a soft tissue fragment which measures 1.3 x 0.5 x 0.2 cm. Clip margin inked in blue. Submitted in toto in one cassette for frozen section.
- D. Received fresh and labeled "Lower lip margin clip superior (skin)" is a soft tissue fragment which measures 1.3 x 0.3 x 0.2 cm. Clip margin inked in blue. Submitted in toto in one cassette for frozen section.
- E. Received fresh and labeled "Mental margin clip superior (skin)" is a soft tissue fragment which measures 1.0 x 0.7 x 0.2 cm. Clip margin is inked in blue. Submitted in toto in one cassette for frozen section.
- F. Received fresh and labeled "Upper cheek margin (skin)" is a soft tissue fragment which measures 1.3 x 0.3 x 0.2 cm. Clip margin inked in blue. Submitted in toto for frozen section in one cassette.
- G. Received fresh and labeled "Nasolabial margin (skin) clip posterior" is a soft tissue fragment which measures 1.5 x 0.3 x 0.2 cm. Clip margin inked in blue. Submitted in toto in one cassette for frozen section.
- H. Received fresh and labeled "Right lower alveolar ridge" is a soft tissue fragment measuring 2.0 x 0.3 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- I. Received fresh and labeled "Right lower gingival labial mucosa margin" is a soft tissue fragment which measures 1.2 x 0.7 x 0.2 cm. Submitted in toto in one cassette

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 11 of 15]
SPEC #:

(Continued)

GROSS DESCRIPTION: (Continued)
for frozen section.

- J. Received fresh and labeled "Lower lip margin clip at oral commissure" is a soft tissue measuring 1.3 x 0.3 x 0.2 cm. Clip margin inked in blue. Submitted in toto in one cassette for frozen section.
- K. Received fresh and labeled "Upper lip mucosal margin" is a soft tissue fragment which measures 1.2 x 0.5 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- L. Received fresh and labeled "Anterior buccal margin clip anterior" is a soft tissue fragment measuring 1.3 x 0.6 x 0.3 cm. Clip margin is inked in blue. Submitted in toto in one cassette for frozen section.
- M. Received fresh and labeled "Posterior buccal margin clip posterior" is a soft tissue fragment measuring 1.5 x 0.5 x 0.3 cm. Clip margin inked in blue. Submitted in toto in one cassette for frozen section.
- N. Received fresh and labeled "Retromolar trigone" is a soft tissue fragment which measures 1.1 x 1.0 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- O. Received fresh and labeled "Retromandibular mucosa margin" is a soft tissue fragment which measures 1.0 x 0.3 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- P. Received fresh and labeled "Posterior buccal fat" is a fibroadipose tissue which measures 2.5 x 1.5 x 0.4 cm. Representative section submitted for frozen and no lesions grossly identified. Sections submitted as follows:
- Cassette #1FS: Frozen section
Cassette #1: Remaining tissue submitted in toto
- Q. Received fresh and labeled "Lower right mandible periosteal margin" is a soft tissue fragment which measures 0.9 x 0.1 x 0.1 cm. Submitted in toto in one cassette for frozen section.
- R. Received in formalin and labeled "Buccal resection, buccal mucosa and cheek skin, lower lip, mental skin suture superior" is a specimen with skin mucosa and fibroadipose tissue which measures 5.5 x 5.0 x 3.0 cm. The skin measures 4.0 x 3.0 x 0.1 cm. A surgical scar on the skin surface measures 2.0 cm in length x 0.1 x 0.1 cm. The mucosa measures 5.0 x 3.0 x 0.1 cm. The external surface of the mucosa is nodular with small focal ulceration which is less than 0.1 cm. Specimen is inked as follows:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 12 of 15]
SPEC #:

(Continued)

GROSS DESCRIPTION: (Continued)

superior, blue; inferior, green; anterior, red; posterior, black. Sectioning reveals a poorly defined nodular tumor which is tan to white. Tumor appears 0.5 cm from the anterior margin, 1.0 cm from posterior margin, less than 0.1 cm from the inferior margin, 1.0 cm from the superior margin. The tumor extends to the mucosal margin. It is 1.0 cm from skin. The tumor measures 2.5 x 2.5 x 3.0 cm. Sections submitted as follows:

Cassette #1: Anterior margin, two fragments

Cassette #2: Posterior margin, two fragments

Cassette #3: Inferior margin

Cassette #4: Superior margin

Cassette #5: Tumor in relation to mucosal margin and ulcerated area and also shows relationship of tumor to skin

Cassettes #6&7: Composite section of tumor with surrounding fat

Cassettes #8&9: Composite section of tumor

Cassette #10: Representative section of brown area extending from tumor

- S. Received in formalin and labeled "Right buccal fat pad" are multiple fragments of adipose tissue which measures 4.0 x 2.0 x 1.0 cm in aggregate. No lesions grossly identified. No lymph nodes. Specimen submitted in toto in cassettes #1-4.
- T. Received in formalin and labeled "Left neck dissection level 1B" is a fibroadipose tissue which measures 5.0 x 4.0 x 2.5 cm. Salivary gland is present which measures 4.6 x 2.5 x 2.0 cm. Largest lymph node measures 2.3 x 0.5 x 0.5 cm. Sections submitted as follows:
- Cassette #1: Largest lymph node bisected
- Cassette #2: Two possible lymph nodes
- Cassette #3: Representative section of salivary gland
- U. Received in formalin and labeled "Left neck dissection level 2A" is a fibroadipose tissue which measures 6.0 x 4.0 x 2.5 cm. Largest lymph node measures 2.0 x 1.0 x 0.5 cm. Sections submitted as follows:
- Cassette #1: Four lymph nodes
- Cassette #2: Four possible lymph nodes
- Cassette #3: Four possible lymph nodes
- Cassette #4: Four possible lymph nodes
- Cassette #5: One lymph node bisected
- Cassette #6: One lymph node bisected
- Cassette #7: One lymph node bisected

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 13 of 15]
SPEC #:

(Continued)

GROSS DESCRIPTION: (Continued)

Cassette #8: One lymph node

- V. Received in formalin and labeled "Right neck dissection level 2B" is a fibroadipose tissue which measures 3.5 x 1.0 x 1.0 cm. Largest lymph node measures 0.6 x 0.5 x 0.3 cm. Sections submitted as follows:

Cassette #1: One lymph node

Cassette #2: Remainder of fibroadipose tissue in toto

- W. Received in formalin and labeled "Right neck dissection levels 1A, 1B, 2A, 3, 4" is a fibroadipose tissue which measures 8.0 x 5.5 x 4.0 cm. Specimen is unoriented. Salivary gland is identified which measures 4.5 x 2.5 x 2.0 cm. Largest lymph node measures 1.7 x 1.0 x 0.6 cm. Sections submitted as follows:

Cassette #1: Largest lymph node bisected

Cassette #2: One lymph node bisected

Cassette #3: One lymph node bisected

Cassette #4: One lymph node bisected

Cassette #5: One lymph node bisected

Cassette #6: Six possible lymph nodes

Cassette #7: Six possible lymph nodes

Cassette #8: Five possible lymph nodes

Cassette #9: Six possible lymph nodes

Cassette #10: One lymph node bisected and representative section of salivary gland

- X. Received in formalin and labeled "Left forearm subcutaneous mass" are small fragments of pale tan/white tissue which measures 1.5 x 1.3 x 1.0 cm in aggregate. Submitted in toto in one cassette.

- Y. Received fresh and labeled "Right thyroid lobe with isthmus" is a right thyroid lobe with isthmus. Specimen weighs 13.82 grams and measures 4.3 x 2.5 x 2.5 cm. Isthmus measures 1.0 x 0.5 x 0.5 cm. External surface is smooth and has no lesions. It is inked in black. There is a nodule in the right lobe which extends from the superior pole through the mid pole which is well circumscribed and measures 3.0 x 2.5 x 2.0 cm. It is yellow and colloid in appearance. There is a small nodule in the isthmus which measures 1.0 x 0.5 x 1.0 cm. It is yellow and well circumscribed. Representative section of large nodule submitted for frozen section. Isthmus margin submitted for frozen section. Remainder of specimen is placed in formalin for permanent. There are some calcifications in the nodule. Remainder of thyroid gland is beefy red brown and unremarkable. Thyroid submitted in toto. Sections submitted as follows:

This report is privileged, confidential and exempt from disclosure under applicable law.

If you receive this report inadvertently, please call [REDACTED] and return the report to us by mail.

[page 14 of 15]
SPEC #:

(Continued)

GROSS DESCRIPTION: (Continued)

Cassette #1FS: Margin at isthmus
Cassette #2FS: Representative section of nodule
Cassettes #1-3: Nodule in superior pole of right lobe
Cassettes #4-7: Nodule in middle pole right lobe
Cassettes #8&9: Nodule in normal thyroid gland tissue and inferior pole right lobe
Cassettes #10&11: Isthmus with nodule in toto
Cassette #11: Two lymph nodes submitted with isthmus

OPERATING ROOM CONSULT

A) Upper lip margin, clip superior, Skin.
Skin. no malignancy Seen.
B) Inferior margin, clip superior, Skin.
Same as A.
C) Inferior lateral margin, Clip Superior, Skin.
Same as A.
D) Lower lip margin, clip superior, Skin.
Same as A.
E) Mental Margin, clip superior, Skin.
Same as A.
F) Upper cheek margin, Skin
Same as A.
G) Naso Labial margin, Skin, Clip Posterior.
Same as A.
H) Right lower alveolar ridge.
No malignancy seen.
I) Right lower gingival labial mucosa margin.
Same as H)
J) Lower lip margin. Clip at oral commissure.
Same as H)
K) Upper lip mucosal margin.
Same as H).
L) Anterior buccal margin. Clip anterior.
Same as H).
M) Posterior Buccal Margin. Clip Posterior.
Same as H)
N) Retromolar trigone.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 15 of 15]
SPEC #:

(Continued)

OPERATING ROOM CONSULT : (Continued)

Same as H)

O) Retromandibular mucosal margin.

Same as H)

P) Posterior Buccal Fat.

Same as H)

Q) Lower right mandible periosteal margin.

Same as H)

Y) Right thyroid lobe with isthmus.

Representative section:

-Follicular lesion.

-Defer final diagnosis for complete sampling and permanent sections.

This report is privileged, confidential and exempt from disclosure under applicable law.

If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

Source: NCI Genomic Data Commons file e625ed31-fc15-4529-b0a5-2aebf3d3b246 (TCGA-IQ-7631.6BA769F5-1902-4A99-80B6-3B297F578E99.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).